Surgical pathology report (de-identified scan), TCGA case TCGA-A6-3810, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-3810-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Sigmoid colon - stitch on distal and staple line at proximal end
- B. Proximal margin of sigmoid colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left colon cancer.

GROSS DESCRIPTION

A. The specimen is received unfixed, labeled "sigmoid colon", and consists of a segment of large bowel, measuring 20 cm. in length and 2.8 cm. in diameter. There is abundant pericolic fat and the entire specimen is up to 10 cm. in diameter. There is a suture at the open end of the specimen, the opposite end is stapled. There is an area of narrowing where an appendix epiploica is adherent to the serosal surface of the colon. This area is 6 cm. from the open end. The bowel is opened with a single incision on the antimesenteric surface. There is a napkin ring-like fungating mucosal tumor, measuring 6 cm. in length and 1.2 cm. in depth. The tumor is circumferential. It is 6 cm. from the distal margin of resection and approximately 11 cm. from the proximal margin. Sections after fixation and clearing. A portion of the specimen is taken for research purposes. The fat is dissected off the colon and there is an area that probably represents pericolic abscess immediately adjacent to the tumor. This area might be associated with diverticulum. MLM:men
Block summary: 1, 2 margins of resection; 3 - 7 tumor; A. 10-22 pericolic lymph nodes.

B. The specimen is received unfixed labeled "proximal margin of sigmoid colon" and consists of a piece of white and yellow soft tissue with staples in it. The specimen measures 4

x

1 x 0.4 cm. RS-1.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

A.

Tumor type: Colonic adenocarcinoma
Tumor grade: 2 out of 3
Tumor size: 6 cm
Distance to nearest margin: 6 cm
Level of penetration: Carcinoma penetrates into pericolic fat.
Margins of resection: Negative for malignancy
Vascular invasion: Absent

Host response: Marked acute and chronic inflammation. One area resembles a diverticulum with pericolic abscess, diverticulum destruction and carcinoma (block A7)
Attached lymph nodes: There is no evidence of malignancy in any of 30 lymph nodes.
Non-lymph node pericolic tumor: Absent
pTNM Stage: T3 N0

B. Negative for malignancy

5, 3

DIAGNOSIS

A. Sigmoid colon, segmental resection:
Moderately differentiated colonic adenocarcinoma

Note: Carcinoma invades through the muscularis propria into pericolic soft tissue. There is no evidence of malignancy in any of 30 pericolic lymph nodes.

B. Sigmoid colon, proximal margin, biopsy: Negative for malignancy

Source: NCI Genomic Data Commons file 71f2cf5d-73a1-42e6-8950-0d0ce1d0acb3 (TCGA-A6-3810.D45C776B-26A5-406A-A4FE-F90896646611.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).